CCDI case PBCDDH — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Bones, joints and articular cartilage of limbs.
https://portal.gdc.cancer.gov/cases/b3422191-1b22-4de1-906d-81762b59b70e

Demographics
Sex at birth: female; Race: asian.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Lower limb, NOS; Age at diagnosis: 4.3 years (1,583 days).

Biospecimens (3 samples)
- Sample 0DPBFB: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DPBFU: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DPBGV: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
